Gene-level copy-number profile of tumor specimen MP2PRT-PARYIG-TMP1-A from MP2PRT case MP2PRT-PARYIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.8 years (3,201 days).
Specimen MP2PRT-PARYIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3cdc3580-c2bd-40a4-b12b-0fd9b81c9e12.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARYIG-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/c44482a2-7ad7-4178-8bae-2019ade4883b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 2: 1,591; copy number 3: 646; copy number 4: 36,275; copy number 5: 2,642; copy number 6: 16,869; copy number 7: 36; copy number 8: 719; copy number 9: 17; copy number 11: 5; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:137,682–157,887, 3 genes: AL627309.7, AL627309.2, RNU6-1100P.
- chr2:88,857,161–89,254,015, 38 genes (within-gene range 0–4): IGKC, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr7:38,239,580–38,340,998, 16 genes: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes (within-gene range 0–2): TRGV5P, TRGV5, TRGV4.
- chr14:22,483,004–22,511,024, 23 genes (within-gene range 0–4): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 23 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–594,768, 10 genes, copy number 9: AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1.
- chr1:631,074–632,616, 2 genes, copy number 9 (within-gene range 4–9): MTCO1P12, AC114498.2.
- chr1:633,535–633,741, 1 gene, copy number 9 (within-gene range 4–9): MTATP8P1.
- chr5:58,198–58,915, 1 gene, copy number 9: AC113430.1.
- chr9:12,134–73,865, 5 genes, copy number 11 (within-gene range 8–11): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr9:39,983,793–40,106,611, 1 gene, copy number 9 (within-gene range 6–9): AL772307.1.
- chr9:40,105,822–40,122,540, 2 genes, copy number 9: AL773545.3, CDRT15P14.
- chr21:46,690,764–46,691,226, 1 gene, copy number 12: RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
